Somatic mutation profile of tumor specimen MP2PRT-PASMRW-TMP1-A (aliquot MP2PRT-PASMRW-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PASMRW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,917 days).
Specimen MP2PRT-PASMRW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eef0467-2735-4321-a368-ecc2460264f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMRW-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMRW-NB1-B-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c27bd295-c9c4-4678-a889-3ca416a7f626

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.6098T>C p.L2033P | Missense Mutation (SNP) | VAF 154/212 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs876660681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH17 | c.12714G>A p.M4238I | Missense Mutation (SNP) | VAF 193/446 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53143270; called by muse, mutect2, varscan2
- ENPP1 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs546032693; called by muse, mutect2, varscan2
- MUC1 | c.3619C>T p.R1207W (on ENST00000611571 / NM_001371720.1; = p.R218W on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 245/602 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774796958, COSV58113767; called by muse, mutect2, varscan2
- PTPRJ | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 159/393 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs771041256, COSV69252513, COSV69254361; called by muse, mutect2, varscan2
- SLC4A3 | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 187/417 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444311990, COSV56093013; called by muse, mutect2, varscan2
- CACNA2D1 | c.1801G>A p.D601N (on ENST00000356253 / NM_001366867.1; = p.D582N on NM_000722.4) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FKBP2 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 272/618 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031442 ATTACTGTCAGACCTGGGGCACTGGCATTCACACAGTGA>TTAGGGG | Missense Mutation (DEL) | VAF 64/144 reads (44%) | called by pindel, varscan2*
- NOS1 | c.4031dup p.K1345Efs*18 | Frame Shift Ins (INS) | VAF 234/636 reads (37%) | called by mutect2, pindel, varscan2
- PCDHB8 | c.1778T>G p.V593G | Missense Mutation (SNP) | VAF 433/1727 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PIK3AP1 | c.2371A>G p.R791G | Missense Mutation (SNP) | VAF 139/367 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- UTRN | c.1098_1099insCGG p.V366_G367insR | In Frame Ins (INS) | VAF 102/138 reads (74%) | called by pindel, varscan2
- UTRN | c.1103G>C p.S368T | Missense Mutation (SNP) | VAF 107/140 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.209); called by muse, varscan2
- AGBL1 | c.1863C>T p.N621= | Silent (SNP) | VAF 158/362 reads (44%) | catalogued as rs757868182, COSV66852867; called by muse, mutect2, varscan2
- OR52B4 | c.831G>A p.P277= | Silent (SNP) | VAF 185/467 reads (40%) | catalogued as rs201717807, COSV68769412; called by muse, mutect2, varscan2
- PIEZO2 | c.7845C>T p.T2615= | Silent (SNP) | VAF 77/172 reads (45%) | called by muse, mutect2, varscan2
- SAFB2 | c.2127C>T p.R709= | Silent (SNP) | VAF 267/634 reads (42%) | catalogued as rs1412101633; called by muse, mutect2, varscan2
- IGLV9-49 | chr22:22343733 del CCC | 3'Flank (DEL) | VAF 83/230 reads (36%) | called by mutect2, pindel, varscan2
